Somatic mutation profile of tumor specimen MP2PRT-PAUPJV-TMP1-A (aliquot MP2PRT-PAUPJV-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUPJV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.7 years (974 days).
Specimen MP2PRT-PAUPJV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbf2bd8b-48ce-4d51-85e3-bb96a4e145e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPJV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPJV-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acef3ab5-168d-43df-ac6d-6f7156ee154e

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/275 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.1907C>T p.A636V (on ENST00000506720 / NM_001322402.2; = p.A568V on NM_015236.6) | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as COSV100800391; called by muse, mutect2, varscan2
- ATN1 | c.1019dup p.G341Wfs*39 | Frame Shift Ins (INS) | VAF 214/699 reads (31%) | called by mutect2, pindel, varscan2
- CFAP99 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 192/461 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 193/495 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MINDY4B | c.1368C>T p.T456= | Silent (SNP) | VAF 118/284 reads (42%) | catalogued as rs116582492; called by muse, mutect2, varscan2
